CCDI case PBBSTE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/2f1c9bef-7814-41f2-893f-2675be9dce00

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Ganglioglioma, NOS: ICD-O-3 morphology code: 9505/1; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 15.0 years (5,493 days).

Biospecimens (3 samples)
- Sample 0DGB90: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DGB9L: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DGBAB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
